FM case AD6267 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/5de8f974-3323-4bc0-b5d2-097f89fa0987

Male, 51.2 years: Acinar adenocarcinoma (ICD-O-3 8550/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
